Gene-level copy-number profile of tumor specimen TCGA-E7-A6MD-01A from TCGA case TCGA-E7-A6MD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.2 years (24,180 days).
Specimen TCGA-E7-A6MD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.4854e50d-7087-4173-be90-b9fa443d28c1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A6MD-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07199bf8-d00c-49ff-9c77-5be2997b2791

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,667; copy number 2: 16,430; copy number 3: 23,288; copy number 4: 7,527; copy number 5: 8,807; copy number 6: 1,533; copy number 7: 256; copy number 9: 46; copy number 11: 55; copy number 15: 76; copy number 20: 7; copy number 21: 7; copy number 22: 101; copy number 23: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A6MD-01A-41D-A34T-01): tumor purity 0.47, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 566 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–8,611,924, 74 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:15,601,341–22,991,582, 72 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:33,956,972–35,256,946, 8 genes, copy number 7 (within-gene range 4–7): LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P.
- chr4:16,501,541–16,898,678, 1 gene, copy number 7 (within-gene range 6–7): LDB2.
- chr4:16,973,275–20,037,972, 27 genes, copy number 7–15: AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63, AC093898.1, AC093871.1, AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1.
- chr11:54,591,480–55,957,630, 59 genes, copy number 7: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1, TRIM51, OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P.
- chr11:68,272,102–71,549,608, 78 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr11:76,435,559–83,423,516, 114 genes, copy number 9–15 (within-gene range 2–15) (broad region; genes not listed).
- chr18:22,798,261–23,672,748, 17 genes, copy number 23 (within-gene range 2–23): RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.
- chr18:23,709,825–23,710,287, 1 gene, copy number 23: RPL23AP77.
- chr20:30,294,550–32,858,751, 81 genes, copy number 22 (within-gene range 2–22) (broad region; genes not listed).
- chr20:35,455,164–36,232,799, 34 genes, copy number 20–22 (within-gene range 2–22): CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1.

Autosomal genes at a single copy (total copy number 1): 1,666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
